Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5745, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5745-01A (Primary Tumor).

TCGA-CH-5745

Diagnosis

1. Predominantly poorly differentiated bilateral multifocal adenocarcinoma of the prostate with growth extending across the organ (Gleason 4+3=7, Gleason 4: 70%). Max. tumor diameter 1.6 cm. Tumor infiltration of periprostatic fatty tissue in the right rectolateral region (invasion front 1 mm, 0.2 mm max. depth) and the right anterior region (invasion front 2 mm, max. 0.1 mm depth). Extensive multifocal tumor involvement of perineural sheaths. Tumor-free surgical preparation margins.

In addition, foci of a prostatic intraepithelial neoplasia (high-grade PIN) and signs of myoglandular prostatic hyperplasia. Focal metaplastic squamous epithelium of the prostatic urethra.

Tumor-free, regular seminal vesicles and seminal ducts.

2. Right obturator fossa lymph nodes: two tumor-free lymph nodes (0/2).
3. Left obturator fossa lymph nodes: three tumor-free lymph nodes (0/3).

Summary tumor classification:

pT3a, max. tumor diameter 16 mm, Gleason 4+3=7 (Gleason 4: 70%), pN0 (0/5), R0.

Remark

The Gleason 4 portion and the periprostatic fatty tissue invasion were already seen in the prior punch biopsy.

Tumor tissue was identified in the region of the yellow-labeled artefactual preparation margins (apex and anterior right). However, the blue and green-labeled surgical preparation margins are tumor-free, so the tumor can be assumed to have been completely excised.

Follow-up report

Microscopy

Immunohistology: CD31, D240, 2 blocks

Communicated tumor classification:

pT3a, maximum tumor diameter 16 mm, Gleason 4+3=7 (Gleason 4: 70%), pN0 (0/5), R0.

Immunohistochemical investigation of two representative tumor blocks showed no evidence of tumorous vessel invasion.

Summary tumor classification:

pT3a, maximum tumor diameter 16 mm, Gleason 4+3=7 (Gleason 4: 70%), L0/V0, pN0 (0/5), R0.

Source: NCI Genomic Data Commons file 02e5b625-fc34-4a27-9828-aaf206371a32 (TCGA-CH-5745.43E941E9-CFBD-45BC-91BB-28E5F5D9B767.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).